Somatic mutation profile of tumor specimen TCGA-A7-A13G-01B (aliquot TCGA-A7-A13G-01B-04D-A22N-09) from TCGA case TCGA-A7-A13G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.3 years (28,969 days).
Specimen TCGA-A7-A13G-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 765357cd-82f5-45b2-be5d-9519251a6c20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A13G-11A (Solid Tissue Normal), aliquot TCGA-A7-A13G-11A-51D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1570f87-5f1c-4d81-bbae-ac039ddba472

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CDC25C | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV60398357; called by muse, mutect2, varscan2
- CEACAM20 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs374925599; called by muse, mutect2, varscan2
- CEP85L | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV63820482, COSV63820833; called by muse, mutect2, varscan2
- CHD7 | c.8096T>A p.M2699K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.888); catalogued as COSV71107371; called by muse, mutect2, varscan2
- CSN1S1 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55889798; called by muse, mutect2, varscan2
- FAT3 | c.5119G>T p.D1707Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV53078923; called by muse, mutect2
- GBP5 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58591473; called by muse, varscan2
- GLI3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.244); catalogued as rs775586921, COSV67885468; called by mutect2, varscan2
- IGHMBP2 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs763336691, COSV99661887, COSV99661992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRBA | c.7958G>C p.G2653A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs764223120, COSV63950263, COSV63950447; called by muse, mutect2, varscan2
- NPC1L1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as rs139110095; called by muse, mutect2, varscan2
- PLEKHA6 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV55330202; called by muse, mutect2, varscan2
- PPP1R7 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52143585; called by muse, mutect2, varscan2
- VWC2L | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs769218522, COSV56965966, COSV56980474; called by muse, mutect2, varscan2
- ZNF180 | c.1187T>A p.L396H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55419831; called by muse, mutect2, varscan2
- ADNP | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- DCAF12L2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA0232 | c.799A>C p.K267Q | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2
- PSMA8 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- RABEP1 | c.1624_1625del p.Q542Vfs*10 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- USP48 | c.990del p.G331Vfs*17 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2842C>T p.L948= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1188911121, COSV101222326; called by muse, mutect2, varscan2
- ASAH2B | c.51C>T p.F17= | Silent (SNP) | VAF 76/234 reads (32%) | catalogued as COSV51767807, COSV99485879; called by muse, varscan2
- C3orf22 | c.84G>A p.P28= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs112901554; called by muse, mutect2, varscan2
- CD163L1 | c.1725C>T p.C575= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV58011432; called by muse, mutect2, varscan2
- F8 | c.2670G>A p.L890= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100811301; called by muse, varscan2
- FNDC1 | c.477C>T p.N159= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV51931308; called by muse, mutect2, varscan2
- GPT | c.342G>T p.A114= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV52952235, COSV52952313, COSV99477330; called by muse, mutect2, varscan2
- MEF2C | c.505C>T p.L169= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV60925892; called by muse, mutect2, varscan2
- PIK3CA | c.3138A>C p.A1046= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1215652300, COSV56029145, COSV99834886; called by muse, mutect2
- TRBV4-1 | c.264C>T p.P88= | Silent (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- UAP1 | c.348C>T p.L116= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs752987749; called by muse, mutect2, varscan2
